TCGA case TCGA-AO-A03N — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9435447e-d65f-408b-863b-6576b1d652dd

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 59 years; Vital status: Alive.

Diagnoses (3)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 59.7 years (21,816 days); Year of diagnosis: 2006; Method of diagnosis: Core Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N1a; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Prior treatment: No; Sites of involvement: Breast, Left Upper Inner / Breast, Left Upper Outer / Breast, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 2; Lymph nodes tested: 19; Micrometastasis present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Treatment intent type: Adjuvant; Days to treatment start: 55 days; Days to treatment end: 153 days; Number of cycles: 4; Prescribed dose: 600; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin; Treatment intent type: Adjuvant; Days to treatment start: 55 days; Days to treatment end: 153 days; Number of cycles: 4; Prescribed dose: 60; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 55 days; Days to treatment end: 153 days; Number of cycles: 4; Prescribed dose: 175; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Anastrozole; Treatment intent type: Adjuvant; Days to treatment start: 207 days; Days to treatment end: 449 days (1.2 years); Prescribed dose: 1; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Letrozole; Treatment intent type: Adjuvant; Days to treatment start: 450 days (1.2 years); Days to treatment end: 820 days (2.2 years); Prescribed dose: 2.5; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Exemestane; Treatment intent type: Adjuvant; Days to treatment start: 821 days (2.2 years); Days to treatment end: 1,007 days (2.8 years); Prescribed dose: 25; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Treatment intent type: Adjuvant; Days to treatment start: 1,007 days (2.8 years); Treatment outcome: Treatment Ongoing; Prescribed dose: 20; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Fulvestrant; Initial disease status: Recurrent Disease; Days to treatment start: 1,639 days (4.5 years); Days to treatment end: 1,667 days (4.6 years); Number of cycles: 3; Treatment dose: 1,500 mg; Route of administration: Intramuscular.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Tesetaxel; Initial disease status: Recurrent Disease; Days to treatment start: 1,699 days (4.7 years); Days to treatment end: 1,762 days (4.8 years); Number of cycles: 4; Treatment dose: 230 mg; Prescribed dose: 27; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 1,814 days (5.0 years); Days to treatment end: 1,828 days (5.0 years); Number of cycles: 2; Treatment dose: 280 mg; Prescribed dose: 80; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Recurrent Disease; Days to treatment start: 1,835 days (5.0 years); Days to treatment end: 1,842 days (5.0 years); Number of cycles: 2; Treatment dose: 2,800 mg; Prescribed dose: 800; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vinorelbine; Initial disease status: Recurrent Disease; Days to treatment start: 1,857 days (5.1 years); Number of cycles: 16; Treatment dose: 704 mg; Treatment outcome: Treatment Ongoing; Prescribed dose: 25; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Denosumab; Initial disease status: Progressive Disease; Days to treatment start: 1,989 days (5.4 years); Number of cycles: 2; Treatment dose: 240 mg; Treatment outcome: Treatment Ongoing; Prescribed dose: 120; Prescribed dose units: mg; Route of administration: Subcutaneous.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Age at diagnosis: 64.2 years (23,461 days); Days to diagnosis: 1,645 days (4.5 years); Prior treatment: Yes.
   Recorded as not given: Surgery, NOS to Locoregional Site, for recurrent disease.
3. Recurrence of diagnosis 1 (Infiltrating duct carcinoma, NOS). Age at diagnosis: 64.2 years (23,461 days); Days to diagnosis: 1,645 days (4.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease; Surgery, NOS to Locoregional Site, for recurrent disease.

Follow-up (2 entries)
- Day 1,645 (post initial treatment): Disease response: With Tumor; Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 1,645 days (4.5 years).
- Follow-up contact recording only the day: day 2,031.

Molecular and laboratory tests
- ERBB2 (IHC): Negative.
- ERBB2 (IHC): Negative; Staining intensity value: 0; Test value range: <10%.
- ESR1 (IHC): Negative; Staining intensity scale: 4 Point Scale.
- ESR1 (IHC): Positive; Staining intensity value: 3+; Test value range: 70-79%.
- PGR (IHC): Negative; Staining intensity scale: 4 Point Scale.
- PGR (IHC): Positive; Staining intensity value: 1+; Test value range: <10%.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AO-A03N-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 360 mg.
  Slide TCGA-AO-A03N-01B-01-TSA: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 1.
  Slide TCGA-AO-A03N-01B-01-BSA: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample TCGA-AO-A03N-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AO-A03N-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: With tumor; Axillary staging method: Sentinel lymph node biopsy plus axillary dissection; Surgical procedure first: Modified Radical Mastectomy; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); Micromet detection by IHC: No; Er IHC score: 3+; Her2 IHC score: 0; Method initial path diagnosis: Core needle biopsy; Her2 IHC percent positive: <10%; Prospective collection: No; Retrospective collection: Yes; Pr status IHC percent positive: <10%.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Left Upper Inner Quadrant; Anatomic organ subdivision: Left Upper Outer Quadrant; Anatomic organ subdivision: Left.
- Follow-up form 1: Tumor status: With tumor; New tumor event surgery: No.
- Follow-up form 2: New tumor event type: Locoregional Disease; New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Drug treatment 1: Regimen number: 2; Pharmaceutical therapy drug name: Femara.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 3: Regimen number: 1.
- Drug treatment 3, Route of administrations: Route of administration: IV.
- Drug treatment 6: Regimen number: 2; Pharmaceutical therapy drug name: Arimidex.
- Drug treatment 7: Regimen number: 2; Pharmaceutical therapy drug name: Aromasin.
- Drug treatment 8: Regimen number: 10.
- Drug treatment 9: Regimen number: 11.
- Drug treatment 10: Regimen number: 9.
- Drug treatment 11: Regimen number: 8.
- Drug treatment 11, Route of administrations: Route of administration: IM.
- Drug treatment 12: Regimen number: 12.
- Drug treatment 13: Regimen number: 13; Pharmaceutical therapy drug name: Xgeva; Therapy regimen: Progression.
- Drug treatment 13, Route of administrations: Route of administration: SC.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,031 days; disease-specific survival: no event (censored), 2,031 days; disease-free interval: event (new tumor event after initially disease-free), 1,645 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,645 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AO-A03N-01B-11D-A10L-01): tumor purity 0.63, ploidy 3.16, whole-genome doublings 1.
